Somatic mutation profile of tumor specimen TCGA-24-1844-01A (aliquot TCGA-24-1844-01A-01W-0639-09) from TCGA case TCGA-24-1844, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.5 years (23,542 days).
Specimen TCGA-24-1844-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22b964e9-63fc-4773-9a87-38a0ffffe109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1844-10A (Blood Derived Normal), aliquot TCGA-24-1844-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2607364d-dd1a-4bf0-b688-212c1e9e472b

The open-access MAF lists 171 somatic variants for this specimen: 139 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 28, Nonsense Mutation 10, Splice Site 4, Frame Shift Del 4, In Frame Del 3, Intron 2, In Frame Ins 1, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 72/87 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs967461896, CM165714, COSV52681947, COSV52682539, COSV52736779, COSV52752470; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4181T>C p.V1394A | Missense Mutation (SNP) | VAF 152/660 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV55296411; called by muse, mutect2, varscan2
- ADH5 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56448801, COSV56449321; called by muse, mutect2, varscan2
- ALOX15 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541366; called by muse, mutect2
- AMY2B | c.465A>C p.K155N | Missense Mutation (SNP) | VAF 18/620 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV100796275, COSV63714839; called by muse, mutect2
- ARHGAP32 | c.1935A>T p.R645S (on ENST00000310343 / NM_001378025.1; = p.R296S on NM_014715.4) | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); catalogued as COSV59853636; called by muse, mutect2, varscan2
- ARNT | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293180795, COSV100591098, COSV100591400; called by muse, mutect2
- ARR3 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV52104994; called by muse, mutect2, varscan2
- ARRDC3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs371971226; called by muse, mutect2, varscan2
- ARSI | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.88); catalogued as rs770795439, COSV60816932, COSV60818487; called by muse, mutect2, varscan2
- ATP8B2 | c.968T>C p.I323T (on ENST00000672630; = p.I290T on NM_001005855.2) | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV59248111; called by muse, mutect2, varscan2
- ATRNL1 | c.3179G>C p.C1060S | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58107447; called by muse, mutect2, varscan2
- BCL2L1 | c.569C>G p.T190S (on ENST00000307677 / NM_001317919.2; = p.T127S on NM_001191.4) | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100304650; called by muse, mutect2
- BHMT | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV57155394; called by muse, mutect2, varscan2
- BRD8 | c.2539G>C p.V847L (on ENST00000254900 / NM_139199.2; = p.V920L on NM_006696.4) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV50163684; called by muse, mutect2, varscan2
- BRWD3 | c.3860G>A p.R1287K | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV64752247; called by mutect2, varscan2
- C11orf54 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV58681779; called by muse, mutect2, varscan2
- CALHM6 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV63991711; called by muse, mutect2, varscan2
- CDH24 | c.714_725del p.L239_S242del | In Frame Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs1036253924; called by mutect2, pindel*
- CEP83 | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV60409098, COSV60410445; called by muse, mutect2, varscan2
- CNTNAP5 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70482035; called by muse, mutect2
- COASY | c.1292T>G p.F431C | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55900026; called by muse, mutect2, varscan2
- COL4A1 | c.4848T>A p.C1616* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV65430111; called by muse, mutect2, varscan2
- CPA2 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV55980989; called by muse, mutect2, varscan2
- CYP4F3 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs143175634; called by muse, mutect2
- CYP8B1 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 7/149 reads (5%) | catalogued as COSV100296125; called by muse, mutect2
- DAG1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.482); catalogued as COSV58186445; called by muse, mutect2, varscan2
- DCTN1 | c.2596C>A p.L866M | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV62621222; called by muse, mutect2, varscan2
- DKK2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761402051, COSV53394372; called by muse, mutect2, varscan2
- DMBT1 | c.7466G>C p.C2489S (on ENST00000338354 / NM_001377530.1; = p.C1732S on NM_004406.3) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57555803; called by muse, mutect2, varscan2
- DOCK2 | c.3436G>A p.D1146N | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1432443241, COSV56980007, COSV99913951; called by muse, mutect2, varscan2
- DOCK2 | c.4612G>T p.A1538S | Missense Mutation (SNP) | VAF 133/399 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56980021; called by muse, mutect2, varscan2
- DPP6 | c.1882G>C p.V628L (on ENST00000377770 / NM_001364500.2; = p.V566L on NM_001936.5) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV100124338, COSV100125012; called by muse, mutect2
- DYNAP | c.34G>T p.E12* (on ENST00000321600; = p.E15* on NM_001307955.1) | Nonsense Mutation (SNP) | VAF 74/199 reads (37%) | catalogued as COSV58666836, COSV58667181; called by muse, mutect2, varscan2
- ECHDC2 | c.738T>G p.I246M (on ENST00000371522 / NM_001198961.2; = p.I215M on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV64302070; called by muse, mutect2, varscan2
- EGR1 | c.73C>G p.H25D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV53520978; called by muse, mutect2, varscan2
- EMILIN2 | c.843A>T p.E281D | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV99598457; called by muse, mutect2
- ERC2 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 32/355 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs373270503; called by muse, mutect2
- ERC2 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 35/476 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.399); catalogued as COSV99883851; called by muse, mutect2
- FPGT-TNNI3K | c.366C>G p.I122M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV100598714, COSV63048695; called by muse, mutect2
- FRY | c.2371C>A p.L791I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.722); catalogued as COSV66576663; called by muse, mutect2, varscan2
- FSCN3 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 39/210 reads (19%) | catalogued as COSV50001843, COSV99133800; called by muse, mutect2, varscan2
- GABBR1 | c.1638C>G p.S546R | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as COSV63544056, COSV63544228; called by muse, mutect2, varscan2
- GAS2L3 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1424231343, COSV57158604; called by muse, mutect2, varscan2
- GFM1 | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51834997; called by muse, mutect2, varscan2
- GJA3 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53836249; called by muse, mutect2
- GOLGA4 | c.3923G>C p.S1308T | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62712983; called by muse, mutect2, varscan2
- GPX6 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100724826; called by muse, mutect2
- GRIK1 | c.2261C>A p.S754Y | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58728436; called by muse, mutect2, varscan2
- HIP1 | c.2731G>T p.A911S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV61190140; called by muse, mutect2, varscan2
- HOOK2 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as COSV53403535; called by muse, mutect2, varscan2
- HTR1F | c.328T>C p.S110P | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138051; called by muse, mutect2
- HTR2C | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.848); catalogued as rs1556423232, COSV52221200; called by muse, mutect2, varscan2
- IL24 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV54321396; called by muse, mutect2, varscan2
- IMPA2 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV52320717, COSV99302712; called by muse, mutect2, varscan2
- ISG20L2 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV57461125; called by muse, mutect2, varscan2
- KLHL21 | c.1424T>A p.V475D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100887227; called by muse, mutect2
- KLHL3 | c.1635T>A p.D545E | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV59056888; called by muse, mutect2, varscan2
- KLRG1 | c.395G>T p.W132L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs749465547, COSV56944694; called by muse, mutect2, varscan2
- KMT2A | c.3634G>C p.A1212P | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV63290733; called by muse, mutect2, varscan2
- KRTAP5-3 | c.482G>C p.C161S | Missense Mutation (SNP) | VAF 155/615 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101294507; called by muse, mutect2, varscan2
- LARP7 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV60522009; called by muse, mutect2, varscan2
- LONP1 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748610478, COSV62262922; called by muse, mutect2, varscan2
- LRRC20 | c.378C>G p.N126K (on ENST00000355790 / NM_207119.3; = p.N76K on NM_018239.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV62938983; called by muse, mutect2, varscan2
- LRRC41 | c.358-2A>T p.X120_splice | Splice Site (SNP) | VAF 66/306 reads (22%) | catalogued as COSV58441681; called by muse, mutect2, varscan2
- LRRC66 | c.1807A>G p.S603G | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs749044498, COSV58636015; called by muse, mutect2, varscan2
- MEGF8 | c.6142C>T p.P2048S (on ENST00000251268 / NM_001271938.2; = p.P1981S on NM_001410.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV52097230; called by muse, mutect2, varscan2
- MIPOL1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV59390976; called by muse, mutect2, varscan2
- MMP1 | c.557A>C p.Q186P | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV59511381; called by muse, mutect2, varscan2
- MTMR2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100656669; called by muse, mutect2
- MYH15 | c.3594G>T p.E1198D | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99843067; called by muse, mutect2
- MYH8 | c.5773G>C p.V1925L | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV67970563; called by muse, mutect2, varscan2
- NAT2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 32/146 reads (22%) | catalogued as COSV54062964; called by muse, mutect2, varscan2
- NCOR2 | c.7011G>A p.M2337I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.901); catalogued as rs1239706649, COSV62302323; called by muse, mutect2, varscan2
- NDUFB5 | c.218T>A p.F73Y | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as COSV52021437; called by muse, mutect2, varscan2
- NLRP5 | c.2713A>C p.K905Q | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as COSV101173612, COSV66766425; called by muse, mutect2
- NR4A1 | c.500A>T p.Y167F | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.706); catalogued as COSV99671240; called by muse, mutect2
- NRBF2 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV53260201; called by muse, mutect2, varscan2
- NUP188 | c.4550G>C p.R1517P | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV100999345, COSV65331759; called by muse, mutect2
- OR10S1 | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73342991; called by muse, mutect2, varscan2
- OR1S1 | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100515361; called by muse, mutect2
- OR4K17 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs757060477, COSV59648883; called by muse, mutect2, varscan2
- OR6C2 | c.288del p.S97Vfs*38 | Frame Shift Del (DEL) | VAF 119/526 reads (23%) | catalogued as COSV59516385; called by mutect2, pindel, varscan2
- PABPC5 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57042700; called by muse, mutect2, varscan2
- PCDHGA6 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54007546; called by muse, mutect2, varscan2
- PDE2A | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs767040419, COSV57811913; called by muse, mutect2, varscan2
- PDGFD | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV56389716; called by muse, mutect2, varscan2
- PDK3 | c.861C>A p.D287E | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64794165; called by muse, mutect2, varscan2
- PHKA1 | c.3076C>A p.P1026T | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV59809745; called by muse, mutect2, varscan2
- PIKFYVE | c.929A>C p.N310T | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs377371097; called by muse, mutect2, varscan2
- PLXNA2 | c.5041C>A p.L1681I | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65443837; called by muse, mutect2, varscan2
- POLR1A | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1360182422, COSV55697788, COSV99808196; called by muse, mutect2, varscan2
- PPP1R3A | c.3298T>C p.F1100L | Missense Mutation (SNP) | VAF 133/594 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.152); catalogued as COSV52890406; called by muse, mutect2, varscan2
- PRAMEF12 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63216272; called by muse, mutect2, varscan2
- PRDM9 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.037); catalogued as rs757609204, COSV57011230; called by muse, mutect2, varscan2
- PRKCA | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as rs561355502, COSV68950843; called by mutect2, varscan2
- PRKCB | c.1723C>T p.L575= | Splice Region (SNP) | VAF 30/184 reads (16%) | catalogued as rs201555288, COSV57764713, COSV57770112; called by muse, mutect2, varscan2
- PSG3 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 101/349 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs756321554, COSV59506313; called by muse, mutect2, varscan2
- PUM3 | c.853-1G>T p.X285_splice | Splice Site (SNP) | VAF 51/263 reads (19%) | catalogued as COSV67397164; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1592G>C p.R531P | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV52864550; called by muse, mutect2, varscan2
- RGS4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63357964; called by muse, mutect2, varscan2
- ROBO2 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as rs1312619080, COSV59932142; called by muse, mutect2, varscan2
- RPS6KA5 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56224365; called by muse, mutect2, varscan2
- SCN8A | c.3110T>G p.L1037W | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV61989911; called by muse, mutect2, varscan2
- SCN9A | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100312521; called by muse, mutect2
- SI | c.2494T>G p.W832G | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52294564; called by muse, mutect2, varscan2
- SLC13A1 | c.1241-1G>A p.X414_splice | Splice Site (SNP) | VAF 56/337 reads (17%) | catalogued as rs1369946851, COSV52015512; called by muse, mutect2, varscan2
- SLC23A3 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV55409082; called by muse, mutect2, varscan2
- SLC31A1 | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs770379332, COSV65264932; called by muse, mutect2, varscan2
- SLC9A7 | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV60385056; called by muse, mutect2
- SLC9A7 | c.2110G>A p.G704R | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100092021; called by muse, mutect2
- SMG1 | c.8276_8278del p.E2759del | In Frame Del (DEL) | VAF 238/502 reads (47%) | catalogued as rs747994041; called by pindel, varscan2
- SNX31 | c.1039T>A p.F347I | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV61264560; called by muse, mutect2, varscan2
- SPATA31A1 | c.2490G>T p.K830N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1292013629; called by mutect2, varscan2
- SPINK14 | c.20T>A p.V7E | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV63659045; called by muse, mutect2, varscan2
- SYNE2 | c.7769A>G p.D2590G | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59964289; called by muse, mutect2, varscan2
- TBC1D14 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1331075065, COSV68986909; called by muse, mutect2, varscan2
- TENT2 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs751485638, COSV57138893; called by muse, mutect2, varscan2
- TLK1 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as rs1431437120, COSV62630978; called by muse, mutect2, varscan2
- TMEM214 | c.1438C>A p.L480M | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.222); catalogued as COSV99476228; called by muse, mutect2, varscan2
- TNS3 | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60796682; called by muse, varscan2
- UGT1A9 | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 247/534 reads (46%) | catalogued as COSV60848609; called by muse, mutect2, varscan2
- USH2A | c.13968G>T p.L4656F | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV56416844; called by muse, mutect2, varscan2
- USP34 | c.10516C>T p.H3506Y | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as rs1384579595, COSV63725666; called by muse, mutect2, varscan2
- UTP20 | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55383309; called by muse, mutect2, varscan2
- WDR6 | c.2866G>C p.V956L | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58246874; called by muse, mutect2, varscan2
- YTHDC1 | c.1178C>G p.S393C (on ENST00000344157 / NM_001031732.4; = p.S375C on NM_133370.4) | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60011649; called by muse, mutect2, varscan2
- ZC3H13 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs768432304, COSV54460852; called by muse, mutect2, varscan2
- ZNF407 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV55265460; called by muse, mutect2, varscan2
- ZNF614 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs376806596, COSV54547837; called by muse, mutect2, varscan2
- ZNF665 | c.1363G>C p.G455R (on ENST00000600412; = p.G520R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67216782; called by muse, mutect2, varscan2
- ZNF804A | c.3229C>A p.P1077T | Missense Mutation (SNP) | VAF 61/504 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as rs141397832, COSV56465104; called by muse, mutect2, varscan2
- CASK | c.2439_2452del p.A814Kfs*50 (on ENST00000378163 / NM_001367721.1; = p.A809Kfs*50 on NM_003688.3) | Frame Shift Del (DEL) | VAF 47/152 reads (31%) | called by mutect2, pindel, varscan2
- HERC2P3 | n.1575-1G>T | Splice Site (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- IGLC7 | c.124T>A p.W42R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5C | c.1524_1532del p.S509_F511del | In Frame Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- LPAR3 | c.874_876dup p.I292dup | In Frame Ins (INS) | VAF 40/164 reads (24%) | called by mutect2, varscan2
- PLEKHA7 | c.3134_3140del p.E1045Afs*25 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- TMEM41A | c.757_778del p.S253Vfs*39 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ABCC9 | c.3957C>T p.V1319= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs778660636, COSV53982237; called by muse, mutect2, varscan2
- ADAMTS19 | c.1831C>T p.L611= | Silent (SNP) | VAF 17/163 reads (10%) | catalogued as COSV50782044; called by muse, mutect2, varscan2
- ADAMTS8 | c.1524A>T p.S508= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV57296139; called by muse, mutect2, varscan2
- AFDN | c.1116G>T p.G372= | Silent (SNP) | VAF 28/257 reads (11%) | catalogued as COSV100652908; called by muse, mutect2, varscan2
- AKNA | c.4014A>C p.P1338= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV56339386; called by muse, mutect2, varscan2
- ARMT1 | c.51A>C p.A17= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV66178967; called by muse, mutect2, varscan2
- ATP2B2 | c.1377G>A p.S459= (on ENST00000352432; = p.S425= on NM_001683.5) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs556206364, COSV59493755; called by muse, mutect2, varscan2
- CCL11 | c.63G>T p.G21= | Silent (SNP) | VAF 222/411 reads (54%) | catalogued as COSV59925550; called by muse, mutect2, varscan2
- CFAP70 | c.273A>G p.P91= | Silent (SNP) | VAF 20/296 reads (7%) | catalogued as COSV100160511; called by muse, mutect2
- DUSP18 | c.60C>A p.L20= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100588819, COSV100588830, COSV100588857; called by muse, mutect2
- DUSP6 | c.972A>G p.K324= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV54379371; called by muse, mutect2, varscan2
- ERC2 | c.1978A>C p.R660= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV55652754; called by muse, mutect2, varscan2
- FKBPL | c.1049G>A p.*350= | Silent (SNP) | VAF 25/330 reads (8%) | catalogued as rs779007293, COSV100913560; called by muse, mutect2
- GMPS | c.1539A>G p.P513= | Silent (SNP) | VAF 44/227 reads (19%) | catalogued as COSV55811205; called by muse, mutect2, varscan2
- ITPRID1 | c.1929C>T p.I643= | Silent (SNP) | VAF 68/189 reads (36%) | catalogued as rs761283475, COSV60072174; called by muse, mutect2, varscan2
- LILRA4 | c.1128C>T p.Y376= | Silent (SNP) | VAF 31/158 reads (20%) | catalogued as rs1327026052, COSV52494112; called by muse, mutect2, varscan2
- NBEAL1 | c.7830T>G p.S2610= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV68916980; called by muse, mutect2, varscan2
- NLRP7 | c.1651C>T p.L551= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV60179715; called by muse, mutect2, varscan2
- OR5T2 | c.729C>A p.G243= | Silent (SNP) | VAF 116/557 reads (21%) | catalogued as rs757984584, COSV100506865, COSV100506913; called by muse, mutect2
- PCDHGA8 | c.1746A>G p.A582= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV54007556; called by muse, mutect2, varscan2
- PIK3R2 | c.1200C>T p.D400= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV55849712; called by muse, mutect2, varscan2
- SCD5 | c.777C>T p.N259= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as rs145735011; called by muse, mutect2, varscan2
- SDHA | c.117G>C p.G39= | Silent (SNP) | VAF 18/147 reads (12%) | catalogued as CD137030, COSV99371562; called by muse, mutect2, varscan2
- SON | c.828G>T p.L276= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV51667834; called by muse, mutect2, varscan2
- TNR | c.2928A>T p.P976= | Silent (SNP) | VAF 105/223 reads (47%) | catalogued as COSV54906476; called by muse, mutect2, varscan2
- TRDMT1 | c.243A>G p.P81= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100003909; called by muse, mutect2
- ZNF587 | c.18G>A p.P6= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as rs1209797311, COSV57150296; called by muse, mutect2, varscan2
- ZNF878 | c.1440A>G p.K480= | Silent (SNP) | VAF 34/398 reads (9%) | catalogued as COSV101521190; called by muse, mutect2
- AARD | c.*2G>A | 3'UTR (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100991881; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849064 A>T | 5'Flank (SNP) | VAF 7/47 reads (15%) | called by mutect2, varscan2
- CR1 | c.487+12091G>T | Intron (SNP) | VAF 30/251 reads (12%) | catalogued as COSV65461818; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11826C>G | Intron (SNP) | VAF 51/301 reads (17%) | catalogued as COSV62063420; called by muse, mutect2, varscan2
